Somatic mutation profile of tumor specimen ALCH-B36T-TTP1-A (aliquot ALCH-B36T-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B36T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,197 days).
Specimen ALCH-B36T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6776cb9-030e-4c60-9351-6eac1219118d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36T-NB1-A (Blood Derived Normal), aliquot ALCH-B36T-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff522cb0-43e4-476e-a776-79a04e374765

The open-access MAF lists 143 somatic variants for this specimen: 98 protein-altering or splice-affecting, 19 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 19, Intron 16, Nonsense Mutation 5, RNA 4, 5'Flank 3, Splice Region 3, 3'UTR 2, Frame Shift Del 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 227/597 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.1825C>A p.R609S | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as CM100190; called by muse, mutect2, varscan2
- AIFM1 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 25/500 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.265); catalogued as COSV99780691; called by muse, mutect2
- ANO7 | c.234G>C p.K78N (on ENST00000274979; = p.K24N on NM_001001666.4) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs758800409; called by muse, mutect2, varscan2
- BDP1 | c.1949T>G p.V650G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.232); catalogued as rs1290576890; called by muse, mutect2
- CACNA2D1 | c.2765C>A p.P922Q (on ENST00000356253 / NM_001366867.1; = p.P910Q on NM_000722.4) | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100667118; called by muse, mutect2
- CFAP47 | c.9160G>T p.E3054* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV66220623; called by muse, mutect2
- COL11A1 | c.2959C>G p.P987A | Missense Mutation (SNP) | VAF 45/604 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62191554; called by muse, mutect2
- CROCC2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as rs1340372356; called by muse, mutect2
- DCAF8L1 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV71595278; called by muse, mutect2, varscan2
- DNAH8 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.027); catalogued as rs1319914179; called by muse, mutect2
- DYSF | c.4404del p.I1469Sfs*17 | Frame Shift Del (DEL) | VAF 40/256 reads (16%) | catalogued as COSV50372292; called by mutect2, pindel, varscan2
- GABBR1 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV100589571, COSV63541166; called by muse, mutect2
- GIGYF1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99308602; called by muse, mutect2
- GOLGB1 | c.4349A>G p.H1450R | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs766705613; called by muse, mutect2, varscan2
- IGHD | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 48/546 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.04); catalogued as COSV66655016; called by muse, mutect2
- LAS1L | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV100408719; called by muse, mutect2
- MAP1B | c.4268G>C p.R1423T | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57103682; called by muse, mutect2, varscan2
- MICAL1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as rs150285580; called by mutect2, varscan2
- MMP16 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 50/653 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54171434; called by muse, mutect2
- NYAP1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745503115; called by muse, mutect2, varscan2
- OR10G7 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.171); catalogued as rs1332506846, COSV57866139; called by muse, mutect2
- OR5AU1 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV58615216; called by muse, mutect2, varscan2
- PCDHA4 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as COSV63539102; called by muse, mutect2, varscan2
- RIMBP2 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs771054251, COSV55468798; called by muse, mutect2, varscan2
- SERPINB4 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs781536461, COSV61986289; called by muse, mutect2, varscan2
- SLITRK2 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1341479535, COSV100157350; called by muse, mutect2
- SOX3 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs1340138478; called by muse, mutect2, varscan2
- SPTA1 | c.3191A>C p.Y1064S | Missense Mutation (SNP) | VAF 10/309 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63757333; called by muse, mutect2
- TEKT2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 65/476 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs768830702; called by muse, mutect2, varscan2
- TENM3 | c.5831G>A p.R1944Q | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV69314176; called by muse, mutect2
- UNC13C | c.1741T>C p.S581P | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV52890012; called by muse, mutect2
- WDR81 | c.4181G>A p.R1394Q (on ENST00000409644 / NM_001163809.2; = p.R343Q on NM_152348.4) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396537736, COSV100489419; called by muse, mutect2, varscan2
- ZNF440 | c.1145C>A p.S382Y | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV58370497; called by muse, mutect2, varscan2
- ACOX1 | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 40/412 reads (10%) | called by muse, mutect2
- ACVR1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRIP | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- BCL11B | c.697G>A p.A233T (on ENST00000357195 / NM_001282237.2; = p.A162T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BTNL9 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA2D1 | c.2764C>A p.P922T (on ENST00000356253 / NM_001366867.1; = p.P910T on NM_000722.4) | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCNDBP1 | c.144T>G p.N48K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2
- CDC25B | c.841-3C>T | Splice Region (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- CEP128 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2
- CSMD3 | c.5813C>A p.P1938H (on ENST00000297405 / NM_001363185.1; = p.P1834H on NM_052900.3) | Missense Mutation (SNP) | VAF 17/448 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CYLD | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CYLD | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, varscan2
- CYP7A1 | c.1325C>G p.T442R | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- DBF4 | c.1495A>T p.N499Y | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- EGFR | c.3595A>T p.R1199W | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2
- FCN1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FLVCR1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 45/367 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GIMAP8 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HDLBP | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2
- IDH3G | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- IGHV3-13 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- INPP4B | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KDM4C | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF21A | c.3322C>T p.L1108= (on ENST00000361418 / NM_001378440.1; = p.L1095= on NM_017641.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- KPNA2 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- MAMLD1 | c.1759T>C p.S587P | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MRGPRX1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 62/491 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- MXRA5 | c.6137C>G p.P2046R | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYT1L | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- NAMPT | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NCKAP5 | c.5536C>A p.P1846T | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NTRK3 | c.927C>A p.S309R | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- NUP98 | c.3926G>T p.W1309L (on ENST00000359171 / NM_001365126.1; = p.W1292L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/473 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5B17 | c.354T>G p.Y118* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- OR6C75 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2
- PABPC5 | c.1037T>A p.V346D | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2
- PCDHA7 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 12/345 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PDS5B | c.2305A>G p.T769A | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.099); called by muse, mutect2
- PIK3AP1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- PIK3C2B | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- PLCE1 | c.1292C>G p.T431R | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); called by muse, mutect2
- POU4F1 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2
- PRAMEF11 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTDSS1 | c.1243-6C>T | Splice Region (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- RGPD4 | c.4849A>G p.K1617E | Missense Mutation (SNP) | VAF 15/512 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.344); called by muse, mutect2
- RHOXF1 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.587); called by muse, mutect2
- RPRML | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- RYK | c.533A>T p.N178I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2
- SEZ6 | c.1934T>C p.V645A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2
- SOCS7 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPRED2 | c.289A>C p.K97Q | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- STK36 | c.2426A>T p.Q809L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCP11L1 | c.403G>T p.G135* | Nonsense Mutation (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- TEKT2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 60/453 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- THEM6 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TMPRSS15 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2
- TNFAIP2 | c.1261A>G p.N421D | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.182); called by muse, mutect2
- TOB1 | c.749C>A p.P250Q | Missense Mutation (SNP) | VAF 49/398 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRPC6 | c.2492A>G p.H831R | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRRAP | c.3055G>C p.E1019Q | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- WDR36 | c.72_74del p.Q24_L25delinsH | In Frame Del (DEL) | VAF 29/247 reads (12%) | called by mutect2, pindel, varscan2
- WDR87 | c.6241C>A p.Q2081K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ZBTB16 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF728 | c.821A>G p.H274R | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATG14 | c.813T>C p.P271= | Silent (SNP) | VAF 28/454 reads (6%) | called by muse, mutect2
- ATP10A | c.2563C>T p.L855= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- CACNA1C | c.459C>T p.N153= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as rs367638447; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAMK4 | c.894G>C p.P298= | Silent (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- CAND1 | c.879T>C p.H293= | Silent (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- CNTN3 | c.1074G>T p.L358= | Silent (SNP) | VAF 15/410 reads (4%) | called by muse, mutect2
- CUBN | c.4236A>T p.P1412= | Silent (SNP) | VAF 13/221 reads (6%) | called by muse, mutect2
- FARP1 | c.3048G>A p.T1016= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs752236183; called by muse, mutect2
- HUWE1 | c.7626C>A p.G2542= | Silent (SNP) | VAF 31/461 reads (7%) | called by muse, mutect2
- KRT10 | c.1023T>C p.N341= | Silent (SNP) | VAF 10/225 reads (4%) | catalogued as rs1274036860; called by muse, mutect2
- OR13D1 | c.834T>C p.I278= | Silent (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- OR1N1 | c.132C>T p.I44= | Silent (SNP) | VAF 16/363 reads (4%) | called by muse, mutect2
- PTPRD | c.3636T>A p.G1212= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- RALGAPA2 | c.2931T>C p.D977= | Silent (SNP) | VAF 30/298 reads (10%) | called by muse, mutect2, varscan2
- RGSL1 | c.1386G>C p.G462= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- RPS6KA1 | c.1206G>T p.S402= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as rs150063775, COSV65177887; called by muse, mutect2
- TAS2R1 | c.700C>T p.L234= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- TENT4A | c.1683C>T p.G561= | Silent (SNP) | VAF 9/193 reads (5%) | called by muse, mutect2
- ZSCAN5C | c.1167C>T p.C389= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as rs556562377, COSV100886161; called by muse, mutect2, varscan2
- ARHGAP22 | c.451+41G>T | Intron (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- ATP8A2 | c.2384+5855C>A | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- C4orf50 | c.-1023C>G | 5'UTR (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- CTPS2 | c.1393+310C>G | Intron (SNP) | VAF 10/64 reads (16%) | called by muse, varscan2
- ERI1 | c.287+906G>C | Intron (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- FAM220BP | n.524C>T | RNA (SNP) | VAF 43/190 reads (23%) | catalogued as rs766078191; called by muse, mutect2, varscan2
- GARS1 | c.1613+10C>T | Intron (SNP) | VAF 18/318 reads (6%) | called by muse, mutect2
- HMGB1P1 | n.595G>A | RNA (SNP) | VAF 15/186 reads (8%) | catalogued as rs1199090368; called by muse, mutect2
- MTFR1L | chr1:25820201 G>A | 5'Flank (SNP) | VAF 24/229 reads (10%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.342G>C | RNA (SNP) | VAF 34/416 reads (8%) | called by muse, mutect2
- OCRL | c.*51G>T | 3'UTR (SNP) | VAF 11/221 reads (5%) | catalogued as COSV100843341; called by muse, mutect2
- PCNX2 | c.4077-27C>T | Intron (SNP) | VAF 13/111 reads (12%) | catalogued as rs775037935; called by muse, mutect2, varscan2
- PIDD1 | c.296-30G>A | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- PRKDC | c.11651+9C>T | Intron (SNP) | VAF 29/219 reads (13%) | called by muse, mutect2, varscan2
- PTPN20 | c.*12G>A | 3'UTR (SNP) | VAF 85/339 reads (25%) | called by muse, mutect2, varscan2
- RASSF4 | c.63-86G>C | Intron (SNP) | VAF 28/167 reads (17%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40557158 A>T | 5'Flank (SNP) | VAF 26/127 reads (20%) | called by muse, varscan2
- SAT1 | c.305-15A>G | Intron (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- SCN1A | c.4852+24A>C | Intron (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- SNORA71E | n.50G>T | RNA (SNP) | VAF 23/236 reads (10%) | called by muse, mutect2, varscan2
- SRPK3 | chrX:153780348 A>C | 5'Flank (SNP) | VAF 41/332 reads (12%) | called by muse, mutect2, varscan2
- TIPARP | c.917+2556A>G | Intron (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- TMC6 | c.272-15C>T | Intron (SNP) | VAF 15/143 reads (10%) | catalogued as rs1161826068, COSV59211545; called by muse, mutect2, varscan2
- UTP14A | c.103-69G>A | Intron (SNP) | VAF 13/153 reads (8%) | called by muse, mutect2
- VDAC2 | c.151-1126C>T | Intron (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2465A>G | Intron (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
